Gene-level copy-number profile of tumor specimen C3N-03076-02 from CPTAC case C3N-03076, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 68.0 years (24,846 days).
Specimen C3N-03076-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 3fb2a6a7-b5f2-4e90-b809-1b8d9fab5514.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-03076-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,719 have no estimate.
https://portal.gdc.cancer.gov/files/d5b388a7-0fbb-4441-9d64-74f606c16a02

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 355; copy number 1: 1,526; copy number 2: 15,459; copy number 3: 16,299; copy number 4: 14,379; copy number 5: 8,559; copy number 6: 1,699; copy number 7: 277; copy number 8: 67; copy number 9: 90; copy number 10: 38; copy number 11: 3; copy number 12: 6; copy number 13: 19; copy number 15: 18; copy number 18: 1; copy number 19: 18; copy number 20: 2; copy number 22: 5; copy number 28: 29; copy number 49: 37; copy number 54: 1; copy number 105: 9; copy number 170: 8.

Homozygous deletions (total copy number 0; autosomes only): 11 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:59,039,761–60,460,739, 7 genes (within-gene range 0–2): AC092343.1, NDUFB4P2, MIR582, AC034234.1, RNU6-806P, AC109486.1, SETP21.
- chr9:83,739,425–83,921,465, 4 genes: GKAP1, AL354733.1, AL354733.2, KIF27.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 628 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:218,419,121–219,912,834, 85 genes, copy number 7 (broad region; genes not listed).
- chr7:66,848,496–67,362,950, 18 genes, copy number 9–22: AC027644.1, GTF2IP23, RNU6-1254P, LINC02604, AC073335.1, Metazoa_SRP, TMEM248, RN7SL43P, SBDS, TYW1, AC073089.1, MIR4650-1, SPDYE21, PMS2P4, Y_RNA, STAG3L4, AC006480.1, AC006480.2.
- chr8:38,269,704–43,284,806, 115 genes, copy number 9–170 (within-gene range 3–170) (broad region; genes not listed).
- chr9:61,190,003–61,662,690, 11 genes, copy number 7–10: SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P, AL935212.3, FAM242D, Y_RNA, AL935212.1.
- chr10:116,545,931–117,375,440, 21 genes, copy number 7: PNLIP, PNLIPP1, PNLIPRP1, PNLIPRP2, C10orf82, AC016825.1, HSPA12A, RPL5P27, ENO4, SHTN1, AC023283.1, AC012308.1, VAX1, MIR3663HG, MIR3663, RPL12P26, KCNK18, AL731557.1, SLC18A2, AL391988.1, PDZD8.
- chr12:55,743,122–56,190,284, 37 genes, copy number 10: GDF11, SARNP, AC023055.1, AC073487.1, ORMDL2, DNAJC14, TMEM198B, MMP19, OLA1P3, GSTP1P1, PYM1, DGKA, AC025162.2, PMEL, CDK2, AC025162.1, RAB5B, AC034102.1, SUOX, IKZF4, AC034102.8, AC034102.3, RPS26, ERBB3, AC034102.2, PA2G4, AC034102.4, RPL41, ESYT1, ZC3H10, AC034102.7, AC034102.6, AC034102.5, MYL6B, MYL6, SMARCC2, AC073896.4.
- chr13:73,413,473–75,859,870, 27 genes, copy number 7–11: LINC00393, LINC00392, KLF12, AL138713.1, AL159972.1, LINC00402, AL353660.1, RNY1P5, RPL21P108, AL355390.1, LINC00381, AL355390.2, LINC00347, RIOK3P1, RNU6-38P, SSR1P2, CTAGE11P, LINC01078, TBC1D4, AL139230.1, COMMD6, UCHL3, AL137782.1, LMO7-AS1, LMO7, AL137244.1, FAM204CP.
- chr16:90,173,217–90,222,851, 1 gene, copy number 18 (within-gene range 2–18): LINC02193.
- chr17:34,169,372–39,864,312, 239 genes, copy number 7–49 (within-gene range 3–49) (broad region; genes not listed).
- chr22:19,875,517–21,070,097, 74 genes, copy number 8–15 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 216. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
